Gene-level copy-number profile of specimen HCM-BROD-0489-C15-85M from HCMI case HCM-BROD-0489-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 63.9 years (23,343 days).
Specimen HCM-BROD-0489-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2508748-d2e6-46dd-b7e0-5111e22a1651.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0489-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/129a754c-3760-45fe-b05e-501327aae75d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,098; copy number 2: 30,223; copy number 3: 20,288; copy number 4: 4,254; copy number 5: 2,746; copy number 6: 120; copy number 7: 57; copy number 8: 2; copy number 9: 22; copy number 11: 64; copy number 16: 18.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,029 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,354,987–120,355,148, 1 gene, copy number 7: U1.
- chr1:143,419,625–191,228,467, 1,351 genes, copy number 5–7 (broad region; genes not listed).
- chr1:191,858,707–191,890,229, 1 gene, copy number 5 (within-gene range 4–5): AL359081.1.
- chr1:238,777,049–242,975,084, 60 genes, copy number 5: MIPEPP2, AL590135.1, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.2, FH, KMO, OPN3, CHML, AL133390.1, WDR64, AL365366.1, EXO1, RPL23AP20, BECN2, CFL1P4, MAP1LC3C, TUBB8P6, BX571673.1, PLD5, AL591686.2, RN7SKP12, AL591686.1, AL360271.2, RPL10AP5, AL360271.1, AC099785.1, RSL24D1P4, AL445675.1, AL445675.2, AL603825.1.
- chr1:244,352,635–248,937,043, 158 genes, copy number 5–6 (broad region; genes not listed).
- chr2:37,816,915–38,239,590, 12 genes, copy number 5: AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12.
- chr2:46,490,750–46,941,855, 12 genes, copy number 5 (within-gene range 4–5): ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2.
- chr2:49,918,503–60,938,604, 126 genes, copy number 5 (broad region; genes not listed).
- chr2:63,050,057–63,087,322, 2 genes, copy number 5: OTX1, AC009501.1.
- chr2:63,108,118–63,119,542, 2 genes, copy number 5: RPL27P5, DBIL5P2.
- chr3:177,816,865–178,007,779, 4 genes, copy number 5: LINC02015, AC007953.1, AC007953.2, RNU6-1120P.
- chr5:19,233,366–19,234,487, 1 gene, copy number 5: HSPD1P15.
- chr9:61,190,003–61,662,690, 11 genes, copy number 6–7: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:62,606,797–62,610,799, 2 genes, copy number 7: RAB28P2, BX005266.3.
- chr10:42,149,310–82,987,179, 707 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:104,641,290–105,265,242, 1 gene, copy number 5 (within-gene range 2–5): SORCS3.
- chr10:105,534,659–128,320,214, 318 genes, copy number 5 (broad region; genes not listed).
- chr11:76,186,325–76,719,801, 16 genes, copy number 5–6: WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP.
- chr12:39,170,646–39,467,345, 3 genes, copy number 5: AC084373.1, KIF21A, AC121334.1.
- chr12:40,140,926–40,224,915, 3 genes, copy number 5 (within-gene range 4–5): LINC02555, LINC02471, LRRK2-DT.
- chr12:41,188,320–41,574,745, 2 genes, copy number 5: PDZRN4, AC090531.1.
- chr12:44,508,275–45,992,120, 20 genes, copy number 5: NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11.
- chr14:98,711,613–98,717,761, 1 gene, copy number 5: C14orf177.
- chr16:46,469,341–46,931,289, 18 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr17:39,927,742–40,527,002, 35 genes, copy number 6: AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1.
- chr17:62,231,470–62,841,645, 24 genes, copy number 8–9: AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3.
- chr18:12,446,512–12,658,134, 1 gene, copy number 5 (within-gene range 3–5): SPIRE1.
- chr18:12,658,043–13,216,367, 16 genes, copy number 5–7: PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1.
- chr20:31,739,271–32,101,856, 15 genes, copy number 5: TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK.
- chr20:32,443,059–32,585,074, 1 gene, copy number 5 (within-gene range 4–5): NOL4L.
- chr20:32,485,149–32,608,893, 5 genes, copy number 5: AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1.
- chr20:44,656,451–44,696,096, 2 genes, copy number 5 (within-gene range 4–5): LINC01260, AL139352.1.
- chr20:54,153,446–54,651,169, 4 genes, copy number 6–7: CYP24A1, PFDN4, AL133335.1, DOK5.
- chr20:62,796,473–64,327,972, 94 genes, copy number 7–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
